Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016447-09A.2 (aliquot TARGET-15-SJMPAL016447-09A.2-01D) from TARGET case TARGET-15-SJMPAL016447, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,285 days).
Specimen TARGET-15-SJMPAL016447-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c71a7c6-2955-4270-aab0-fe37243f0e33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016447-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016447-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae22e229-10b4-4cc0-a786-e0951bfe535f

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, Frame Shift Ins 2, Silent 2, 5'Flank 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 61/137 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- ARHGEF10 | c.1057G>A p.A353T (on ENST00000398564; = p.A328T on NM_014629.4) | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs977083004, COSV50643604; called by muse, mutect2, varscan2
- COL26A1 | c.886G>A p.V296M (on ENST00000313669 / NM_001278563.3; = p.V294M on NM_133457.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as rs768037612; called by muse, mutect2, varscan2
- KCNA4 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as COSV60251905; called by muse, mutect2, varscan2
- NOTCH1 | c.7312_7313dup p.S2439Rfs*39 | Frame Shift Ins (INS) | VAF 51/99 reads (52%) | catalogued as COSV53047255, COSV53052980, COSV53102645; called by mutect2, pindel, varscan2
- PPP3CA | c.1450C>A p.P484T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59919482; called by muse, varscan2
- ZNF598 | c.1667_1672del p.D556_G557del | In Frame Del (DEL) | VAF 4/38 reads (11%) | catalogued as rs781335477; called by pindel, varscan2
- BRD9 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.039); called by muse, mutect2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 32/84 reads (38%) | called by mutect2, pindel
- CTSV | c.812G>T p.S271I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- FADS3 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- SCML4 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- SLC6A14 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.54059G>T p.G18020V (on ENST00000591111; = p.G10596V on NM_003319.4) | Missense Mutation (SNP) | VAF 189/383 reads (49%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY4 | c.5179C>A p.Q1727K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- CACNA1I | c.252C>A p.V84= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- DSG2 | c.1872C>A p.L624= | Silent (SNP) | VAF 70/168 reads (42%) | catalogued as rs1321243877; called by muse, varscan2
- CAPZA2 | chr7:116862572 del GCT | 5'Flank (DEL) | VAF 5/59 reads (8%) | catalogued as rs754710280; called by mutect2, pindel
- G3BP1 | c.351+1001C>T | Intron (SNP) | VAF 43/74 reads (58%) | called by muse, mutect2, varscan2
- GTSF1 | c.118-11dup | Intron (INS) | VAF 84/183 reads (46%) | called by mutect2, pindel, varscan2
